Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A29G, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A29G-06A (Metastatic).

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Melanoma. Right occipital lesion - histopathology. Scalp lesion. Tumour Banking. 1. Scalp lesion- section taken for Tumour Banking. (Note there is a diagram on the request form explaining where the tumour banking section was taken from). 2. (R) occipital- No tumour banking specimen taken.

MACROSCOPIC DESCRIPTION

(Dr

Two specimens were received.

ICD - 0-3

Melanoma, NOS 8720/3

Site: Skin, scalp c44.4

4/14/11

1. "SCALP LESION". An ellipse of skin 62 x 34mm to a depth of 5mm, bearing a centrally pale nodule 17 x 17mm. A section has been taken from the nodule for tumour banking. Surgical margins inked blue and black differentially. The cut surface reveals the nodule to be darkly pigmented. Five serial sections made through the lesion embedded in block A to E consecutively. Both poles are macroscopically uninvolved.

2. "RIGHT OCCIPITAL LESION". An unorientated ellipse of skin 42 x 17mm to a depth of 21mm, bearing a scar at one pole 7 x 2mm. A palpable nodule is located within the subcutaneous tissue 9 x 7 x 7mm. Surgical margins inked blue. Three transverse sections made through the lesion embedded in blocks A to C consecutively.

MICROSCOPIC REPORT

1. "SCALP LESION"

The sections show skin to the level of subcutis. Within the reticular dermis and subcutis is a 15mm, well-circumscribed, unencapsulated tumour nodule, composed of epithelioid cells with oval, pleomorphic nuclei, prominent nucleoli and with a brisk mitotic rate. An area of necrosis is noted. Many cells contain intracytoplasmic brown pigment, and abundant melanophages are present. The tumour cells are positive for S100, HMB45 and Melan A. The features are those of melanoma, and given the location and the lack of connection to the overlying, unremarkable epidermis would be consistent with metastatic melanoma. The tumour nodule is 0.1mm from the deep margin and 5mm from the radial margins.

2. "RIGHT OCCIPITAL LESION"

The sections show skin to the level of subcutis. Within the subcutis is a 7mm tumour nodule with similar appearance to specimen 1 and consistent with metastatic melanoma, which lies 0.5mm from the deep margin. This lies next to a large vessel in the subcutis.

SUMMARY

1. Skin, scalp -

MELANOMA.

2. Skin, right occipital region - MELANOMA.

REPORTED BY: Dr.

A Unit of

TCGA specimen on TSS.

Primary Discrepancy		

Printed: 4/14/11

Source: NCI Genomic Data Commons file 13c79736-11f1-41b5-a57c-08298be5d72f (TCGA-EE-A29G.69D08E23-4BA3-4C50-9544-801889AB74AB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).